Somatic mutation profile of tumor specimen TCGA-XC-AA0X-01A (aliquot TCGA-XC-AA0X-01A-32D-A401-08) from TCGA case TCGA-XC-AA0X, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 77.2 years (28,211 days).
Specimen TCGA-XC-AA0X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c417970a-4f48-4522-a38a-b1617ffaebb8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XC-AA0X-10A (Blood Derived Normal), aliquot TCGA-XC-AA0X-10A-01D-A401-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac438107-3dbf-43a0-b65e-69794be9aedf

The open-access MAF lists 195 somatic variants for this specimen: 146 protein-altering or splice-affecting, 46 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 124, Silent 46, Nonsense Mutation 10, Frame Shift Del 5, In Frame Del 2, Splice Site 2, RNA 1, Splice Region 1, Frame Shift Ins 1, Translation Start Site 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MKRN3 | c.482del p.P161Rfs*10 | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | catalogued as rs763195944; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SGCG | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 16/99 reads (16%) | catalogued as rs1566011034, COSV54556719, COSV99523529; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 18/75 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.632C>T p.S211L | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.234); catalogued as COSV59386522; called by muse, mutect2
- ABCG8 | c.833G>A p.R278K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV99700390; called by muse, mutect2, varscan2
- ACAD10 | c.2860G>A p.G954S | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV100564733; called by muse, mutect2, varscan2
- ADGRE1 | c.2114C>A p.S705Y | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99166015; called by muse, mutect2
- ADGRV1 | c.16021A>G p.I5341V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV101316675; called by muse, mutect2
- AFF2 | c.542T>C p.M181T | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs782480868, COSV60658625; called by muse, mutect2, varscan2
- ANK2 | c.3422G>T p.R1141L | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100004727; called by muse, mutect2, varscan2
- ANK2 | c.6596A>G p.D2199G | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV100004728; called by muse, mutect2, varscan2
- APBB2 | c.1405G>A p.D469N (on ENST00000295974 / NM_001166050.2; = p.D470N on NM_004307.2) | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs931995085, COSV99924346; called by muse, mutect2, varscan2
- ARHGEF40 | c.3906G>T p.K1302N | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100070785; called by muse, mutect2
- ASB4 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.27); catalogued as rs1053495811, COSV100367357; called by muse, mutect2
- ASPG | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV71933600; called by muse, mutect2, varscan2
- ATP2A2 | c.2387T>C p.L796P | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100428999; called by muse, mutect2
- ATRNL1 | c.3689T>A p.L1230H | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs1554984636, COSV100373181; called by muse, mutect2, varscan2
- BMPER | c.362G>A p.W121* | Nonsense Mutation (SNP) | VAF 20/80 reads (25%) | catalogued as COSV99780802; called by muse, mutect2, varscan2
- BRINP3 | c.1867G>C p.E623Q | Missense Mutation (SNP) | VAF 13/252 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100819524, COSV100819608; called by muse, mutect2
- C10orf71 | c.1022G>A p.G341E | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as rs753223471, COSV100110753, COSV60509562; called by muse, mutect2, varscan2
- C1GALT1C1 | c.703G>C p.E235Q | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV100485662; called by muse, mutect2, varscan2
- C21orf62 | c.116C>A p.T39N | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.915); catalogued as COSV101212369; called by muse, mutect2, varscan2
- CADPS | c.1956C>G p.I652M | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV99340223, COSV99341496; called by muse, mutect2, varscan2
- CARD11 | c.1177T>C p.Y393H | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.894); catalogued as COSV101211078; called by muse, mutect2, varscan2
- CBLIF | c.504C>A p.F168L | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.496); catalogued as COSV99951122; called by muse, mutect2
- CBLIF | c.503T>A p.F168Y | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV99951123; called by muse, mutect2, varscan2
- CC2D2B | c.634G>C p.D212H | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as COSV100729598; called by muse, mutect2, varscan2
- CCDC73 | c.2216C>T p.P739L | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as COSV100068508; called by muse, mutect2
- CD177 | c.1136T>C p.F379S | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1482827229, COSV100946106; called by muse, mutect2, varscan2
- CEACAM18 | c.817C>G p.L273V | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.236); catalogued as rs200888693; called by muse, mutect2
- CEP350 | c.8159T>A p.L2720Q | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100855427; called by muse, mutect2
- CNGB3 | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs555345043, COSV60684228; called by muse, mutect2, varscan2
- CNTNAP4 | c.1469C>A p.T490N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.493); catalogued as rs1219174577, COSV100270034; called by muse, mutect2, varscan2
- CPQ | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.356); catalogued as COSV99615515; called by mutect2, varscan2
- CPXM2 | c.1553G>A p.G518D | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99583575; called by muse, mutect2
- CSF2RB | c.2134G>T p.V712F | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV99454633; called by muse, mutect2, varscan2
- CYP19A1 | c.508A>G p.T170A | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99548268; called by muse, mutect2
- DAAM1 | c.2423G>T p.G808V | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs367677783; called by muse, mutect2
- DIP2B | c.4710C>G p.I1570M | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99999662; called by muse, mutect2
- DMP1 | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.231); catalogued as COSV99219081; called by muse, mutect2
- DNAH5 | c.13693C>A p.P4565T | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99455406; called by muse, mutect2
- DNAI3 | c.40A>C p.K14Q | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV99642545; called by muse, mutect2, varscan2
- ELF3 | c.893G>T p.R298L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV100668963; called by muse, mutect2
- EPHA4 | c.2017A>G p.I673V | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV99917720; called by muse, mutect2, varscan2
- EXPH5 | c.281-2A>G p.X94_splice | Splice Site (SNP) | VAF 8/68 reads (12%) | catalogued as COSV99762387; called by muse, mutect2
- F8 | c.4825A>G p.T1609A | Missense Mutation (SNP) | VAF 16/241 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as rs1269626654, CD101347, COSV100812103; called by muse, mutect2
- FAM184A | c.1232A>T p.N411I | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV100138450; called by muse, mutect2, varscan2
- FASLG | c.638T>C p.M213T | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100390736; called by muse, mutect2, varscan2
- FAT4 | c.6704G>A p.G2235D | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100630560, COSV58674734; called by muse, mutect2
- FBLN1 | c.1788C>G p.I596M | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); catalogued as COSV59937180; called by muse, mutect2, varscan2
- FBXW8 | c.39C>G p.I13M (on ENST00000309909; = p.I51M on NM_012174.1) | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs1255063638, COSV59298550, COSV59304882; called by muse, mutect2
- FMN2 | c.2884G>T p.A962S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.018); catalogued as COSV100147749, COSV99070455; called by muse, varscan2
- GK5 | c.1308G>A p.R436= | Splice Region (SNP) | VAF 10/76 reads (13%) | catalogued as COSV101242360; called by muse, mutect2, varscan2
- GPA33 | c.563C>G p.A188G | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as COSV100901319; called by muse, mutect2, varscan2
- GPRIN2 | c.1112G>T p.S371I | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.249); catalogued as COSV65400744; called by muse, mutect2, varscan2
- HERC2 | c.13063C>A p.H4355N | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as COSV55350698; called by muse, mutect2
- HNRNPUL2 | c.1411A>T p.K471* | Nonsense Mutation (SNP) | VAF 20/146 reads (14%) | catalogued as COSV100079913; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1032C>A p.H344Q | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as COSV100150752, COSV100151539; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1436C>A p.P479Q | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1261746031, COSV100151542; called by muse, mutect2, varscan2
- KCNAB1 | c.386A>C p.Y129S (on ENST00000490337 / NM_172160.3; = p.Y118S on NM_003471.3) | Missense Mutation (SNP) | VAF 78/196 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100205303, COSV56753710; called by muse, mutect2, varscan2
- KEAP1 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV50302633, COSV99407963; called by muse, mutect2, varscan2
- LARP1B | c.1336A>C p.N446H | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99219073; called by muse, mutect2
- LTBP4 | c.4036G>A p.D1346N (on ENST00000308370 / NM_001042544.1; = p.D1309N on NM_003573.2) | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as rs1337949401, COSV99199793; called by muse, mutect2, varscan2
- MAGEB10 | c.442C>A p.Q148K | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as COSV63313149; called by muse, mutect2, varscan2
- MAP3K13 | c.952G>T p.A318S | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.941); catalogued as COSV53988325, COSV99408177; called by muse, mutect2, varscan2
- MAP3K15 | c.609A>T p.R203S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.68); catalogued as COSV100136030; called by muse, mutect2, varscan2
- MARS2 | c.1631C>T p.S544L | Missense Mutation (SNP) | VAF 6/135 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as COSV56572234; called by muse, mutect2
- MCTP1 | c.1933+2T>A p.X645_splice | Splice Site (SNP) | VAF 16/62 reads (26%) | catalogued as COSV100388440; called by mutect2, varscan2
- MINDY4 | c.488A>C p.K163T | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as COSV99519428; called by muse, mutect2
- MON2 | c.2090C>A p.S697* | Nonsense Mutation (SNP) | VAF 15/138 reads (11%) | catalogued as COSV99743943; called by muse, mutect2
- MT4 | c.101G>A p.C34Y | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99533819; called by muse, mutect2
- MUC7 | c.349C>A p.P117T | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as COSV100512414; called by muse, mutect2, varscan2
- MYO5C | c.781T>G p.Y261D | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99955798; called by mutect2, varscan2
- NEK2 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs757031845, COSV65356740; called by muse, varscan2
- NID1 | c.2074C>T p.Q692* | Nonsense Mutation (SNP) | VAF 9/41 reads (22%) | catalogued as COSV99938479; called by muse, mutect2, varscan2
- NIPAL3 | c.179G>C p.R60P | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV99135666; called by muse, mutect2, varscan2
- NKRF | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100441949; called by muse, mutect2, varscan2
- NLGN1 | c.2042C>T p.A681V | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100850376; called by muse, mutect2, varscan2
- NRXN3 | c.621C>A p.F207L (on ENST00000557594 / NM_001272020.2; = p.F839L on NM_004796.6) | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV99822629; called by muse, mutect2, varscan2
- OR1C1 | c.187del p.S64Vfs*19 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | catalogued as COSV68715595; called by mutect2, pindel
- OR56A1 | c.362T>A p.M121K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100360577; called by muse, mutect2
- OR5D16 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as COSV101004169; called by muse, mutect2, varscan2
- OR8H3 | c.56C>A p.S19* | Nonsense Mutation (SNP) | VAF 19/128 reads (15%) | catalogued as rs1372533028, COSV99046767; called by muse, mutect2, varscan2
- OR9A2 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100628305; called by muse, mutect2, varscan2
- PDE10A | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV100606104; called by muse, mutect2, varscan2
- PDS5B | c.290A>T p.Y97F | Missense Mutation (SNP) | VAF 27/199 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100221642; called by muse, mutect2, varscan2
- PGM3 | c.341C>G p.A114G | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV99392603; called by muse, mutect2, varscan2
- PHF8 | c.511A>T p.M171L (on ENST00000357988 / NM_001184896.1; = p.M135L on NM_015107.3) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV100155046; called by muse, mutect2, varscan2
- PKHD1 | c.4420G>A p.G1474R | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.94); catalogued as COSV61874972; called by muse, mutect2
- PRB1 | c.152C>A p.P51Q | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as rs1346718463, COSV99556146; called by muse, mutect2
- PSMD5 | c.170A>G p.H57R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs768858837, COSV99270961; called by muse, mutect2
- PTBP2 | c.274A>G p.K92E (on ENST00000426398 / NM_001300986.2; = p.K84E on NM_021190.4) | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.79); catalogued as rs1408008215, COSV100930299; called by muse, mutect2, varscan2
- PTDSS2 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs756402872, COSV100339354; called by muse, mutect2
- PTPRM | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 8/61 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV100161295; called by muse, varscan2
- PTPRZ1 | c.6433G>T p.E2145* | Nonsense Mutation (SNP) | VAF 8/100 reads (8%) | catalogued as COSV101100935; called by muse, mutect2
- PUS10 | c.649C>A p.P217T | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.268); catalogued as COSV100369876; called by muse, mutect2, varscan2
- RAB3GAP2 | c.2682G>T p.E894D | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.662); catalogued as COSV100741525; called by muse, mutect2, varscan2
- RAI2 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100518588; called by muse, mutect2
- REV1 | c.851G>T p.R284I | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV99301636; called by muse, mutect2, varscan2
- RYR2 | c.9344A>C p.H3115P | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV100773291; called by muse, mutect2
- SALL1 | c.325G>T p.D109Y | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV99192446; called by muse, mutect2, varscan2
- SAMD4A | c.292A>G p.K98E | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99200874; called by muse, mutect2
- SAP130 | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV52100165; called by muse, mutect2, varscan2
- SEMA3A | c.707A>G p.D236G | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.869); catalogued as COSV99548265; called by muse, mutect2
- SEMA5A | c.3085G>T p.D1029Y | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as COSV101228772; called by muse, mutect2, varscan2
- SEMA5A | c.3084C>A p.Y1028* | Nonsense Mutation (SNP) | VAF 29/158 reads (18%) | catalogued as COSV101228773, COSV66789300; called by muse, mutect2, varscan2
- SERPINB2 | c.1228G>T p.G410C | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99449820; called by muse, mutect2
- SERPINI2 | c.1126A>G p.K376E | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV99248599; called by muse, mutect2, varscan2
- SLC6A11 | c.830G>T p.G277V | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99595153; called by muse, mutect2
- SLC6A15 | c.1208A>G p.Y403C | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99881682; called by muse, mutect2, varscan2
- SPATA31E1 | c.2858A>T p.H953L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV100351232; called by muse, mutect2, varscan2
- SPEN | c.296C>A p.S99Y | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101005730; called by muse, mutect2
- SUGCT | c.1138A>T p.K380* (on ENST00000335693 / NM_001193313.2; = p.K406* on NM_024728.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/132 reads (8%) | catalogued as COSV100005202; called by muse, mutect2
- TAF1L | c.2409G>T p.Q803H | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99067979; called by muse, mutect2, varscan2
- TBC1D25 | c.1745C>A p.P582H | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as COSV100952256; called by muse, mutect2, varscan2
- TENM1 | c.1100G>T p.G367V | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.077); catalogued as COSV100951244, COSV64425764; called by muse, mutect2, varscan2
- TENT5D | c.701G>A p.G234D | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57639482; called by muse, mutect2
- TLR4 | c.1122C>G p.S374R (on ENST00000355622 / NM_138554.5; = p.S334R on NM_003266.4) | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.408); catalogued as COSV100842907, COSV62923288, COSV62924132; called by muse, mutect2
- TMC2 | c.849G>T p.M283I | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV100728058, COSV62650957; called by muse, mutect2, varscan2
- TMEM81 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.929); catalogued as COSV99056960, COSV99196985; called by muse, mutect2, varscan2
- TPTE | c.1162C>A p.P388T (on ENST00000618007 / NM_199261.4; = p.P370T on NM_199259.4) | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759137049; called by muse, mutect2
- TTN | c.45668C>A p.A15223D (on ENST00000591111; = p.A7799D on NM_003319.4) | Missense Mutation (SNP) | VAF 30/92 reads (33%) | PolyPhen probably damaging (0.999); catalogued as COSV100634889; called by muse, mutect2, varscan2
- TTN | c.15367A>T p.S5123C (on ENST00000591111; = p.S4196C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/49 reads (22%) | PolyPhen benign (0); catalogued as COSV100634894; called by muse, mutect2, varscan2
- TYR | c.1115G>C p.G372A | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD153203, COSV54479390, COSV99635617; called by muse, mutect2, varscan2
- UBE2G2 | c.102T>A p.F34L | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.075); catalogued as COSV100446187; called by muse, mutect2, varscan2
- URGCP | c.1271G>A p.S424N (on ENST00000453200 / NM_001077663.3; = p.S415N on NM_017920.4) | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99788065; called by muse, mutect2, varscan2
- USH2A | c.9882C>A p.C3294* | Nonsense Mutation (SNP) | VAF 15/84 reads (18%) | catalogued as CM139545, COSV100244028; called by muse, mutect2, varscan2
- USP28 | c.463A>G p.R155G | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99137161; called by muse, mutect2, varscan2
- UTP14A | c.1411C>T p.H471Y | Missense Mutation (SNP) | VAF 27/231 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); catalogued as COSV100929029; called by muse, mutect2, varscan2
- VPS54 | c.1379T>C p.I460T | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.075); catalogued as COSV99708937; called by muse, mutect2
- VWA3A | c.1672A>T p.S558C | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as COSV100241378; called by muse, mutect2, varscan2
- ZBBX | c.1087A>T p.S363C | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV100285120; called by muse, varscan2
- ZCCHC13 | c.355G>T p.G119W | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100272502; called by muse, mutect2
- ZNF334 | c.40G>C p.D14H | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1475253568, COSV100749242; called by muse, mutect2, varscan2
- ZNF518A | c.3402G>C p.K1134N | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100283790; called by muse, mutect2
- ZNF573 | c.1750T>C p.C584R (on ENST00000536220 / NM_001172692.1; = p.C526R on NM_152360.3) | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100265892; called by muse, mutect2
- FIGN | c.734A>T p.Y245F | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- NCOR2 | c.1995delinsTT p.L666Ffs*38 | Frame Shift Ins (INS) | VAF 16/136 reads (12%) | called by pindel, varscan2*
- PDE5A | c.1995del p.Q666Sfs*25 | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | called by mutect2, pindel, varscan2
- PPA2 | c.394_408del p.I132_K136del | In Frame Del (DEL) | VAF 16/161 reads (10%) | called by mutect2, pindel
- RAD21 | c.1085_1096del p.M362_E365del | In Frame Del (DEL) | VAF 10/108 reads (9%) | called by mutect2, pindel
- SLC17A7 | c.1576G>T p.D526Y | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.037); called by muse, mutect2
- UBE2NL | c.230A>T p.Y77F | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.187); called by muse, mutect2
- USP43 | c.3201del p.S1068Afs*45 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | called by mutect2, pindel, varscan2
- VPS13D | c.11472_11478del p.E3824Dfs*6 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | called by mutect2, pindel
- ZNF658 | c.659C>T p.S220F | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2
- ACIN1 | c.2565A>G p.T855= | Silent (SNP) | VAF 25/146 reads (17%) | catalogued as COSV99400512; called by muse, mutect2, varscan2
- AFAP1L1 | c.2079G>A p.V693= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV99696205; called by muse, mutect2, varscan2
- BMP15 | c.1146G>A p.E382= | Silent (SNP) | VAF 18/133 reads (14%) | catalogued as COSV99399576; called by muse, mutect2, varscan2
- BSN | c.10638C>T p.D3546= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as rs746623961, COSV99610131; called by muse, mutect2, varscan2
- CACNA2D4 | c.2049T>A p.G683= | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as COSV99766767; called by muse, mutect2, varscan2
- CCDC148 | c.327A>G p.T109= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs1323125059, COSV99321706; called by muse, mutect2, varscan2
- CCDC39 | c.1899T>C p.S633= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs1255953289, COSV99870937; called by muse, mutect2, varscan2
- CD177 | c.792C>T p.G264= | Silent (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2, varscan2
- CEP350 | c.8158C>T p.L2720= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV100855426; called by muse, mutect2
- CEP76 | c.1866C>T p.I622= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as rs761143650, COSV100043060; called by muse, mutect2
- CNNM4 | c.531G>A p.G177= | Silent (SNP) | VAF 40/210 reads (19%) | catalogued as COSV65660902; called by muse, mutect2, varscan2
- DCAF12L1 | c.981C>A p.S327= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV100948485; called by muse, mutect2, varscan2
- ELAVL4 | c.195C>G p.L65= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as COSV100836966; called by muse, mutect2, varscan2
- ERCC6L | c.1983C>G p.A661= | Silent (SNP) | VAF 23/122 reads (19%) | catalogued as COSV100559300; called by muse, mutect2, varscan2
- EVC | c.579C>A p.L193= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV99382750; called by muse, mutect2, varscan2
- FAM71C | c.336A>G p.A112= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as COSV100175860; called by muse, mutect2, varscan2
- FBXW4 | c.957G>A p.E319= | Silent (SNP) | VAF 12/166 reads (7%) | catalogued as COSV100489619; called by muse, mutect2
- HUWE1 | c.10140C>T p.S3380= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV99474808; called by muse, mutect2, varscan2
- KBTBD8 | c.1030A>C p.R344= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV99805986; called by muse, mutect2, varscan2
- LETM2 | c.486A>G p.R162= (on ENST00000379957 / NM_001286819.2; = p.R115= on NM_144652.3) | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as COSV99907678; called by muse, mutect2, varscan2
- MASP2 | c.609G>A p.R203= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV101280482; called by muse, mutect2, varscan2
- MED13 | c.6420C>A p.L2140= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV101181519, COSV67264941; called by muse, mutect2, varscan2
- MUC5B | c.12333G>A p.L4111= | Silent (SNP) | VAF 8/143 reads (6%) | called by muse, mutect2
- NAT10 | c.2652T>C p.I884= | Silent (SNP) | VAF 11/131 reads (8%) | catalogued as COSV99140622; called by muse, mutect2
- NSL1 | c.243A>G p.E81= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV100875297; called by muse, mutect2, varscan2
- OGT | c.1002C>T p.A334= | Silent (SNP) | VAF 18/159 reads (11%) | catalogued as COSV101035678; called by muse, mutect2, varscan2
- OR2A5 | c.42G>T p.L14= | Silent (SNP) | VAF 7/72 reads (10%) | called by muse, mutect2, varscan2
- OR5R1 | c.123C>A p.G41= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as rs568499294, COSV100393184; called by muse, mutect2, varscan2
- PDE6A | c.1053C>T p.A351= | Silent (SNP) | VAF 15/164 reads (9%) | catalogued as COSV99678817; called by muse, mutect2
- PHF8 | c.510C>A p.G170= (on ENST00000357988 / NM_001184896.1; = p.G134= on NM_015107.3) | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV100155050; called by muse, mutect2, varscan2
- RAPGEF2 | c.1725A>G p.A575= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as rs1218303015, COSV100031820; called by muse, mutect2, varscan2
- REEP3 | c.219C>G p.V73= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV100005316; called by muse, mutect2, varscan2
- SEC61A1 | c.870C>A p.P290= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as COSV99685091; called by muse, mutect2, varscan2
- SENP2 | c.444C>T p.S148= | Silent (SNP) | VAF 33/247 reads (13%) | catalogued as COSV99958362; called by muse, mutect2, varscan2
- SLC20A2 | c.720G>A p.R240= | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as COSV100646275; called by muse, mutect2, varscan2
- SMG8 | c.600C>T p.L200= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs983526608, COSV99959161; called by muse, mutect2, varscan2
- SRCAP | c.2034G>T p.V678= | Silent (SNP) | VAF 9/121 reads (7%) | catalogued as COSV99351637; called by muse, mutect2
- SSH2 | c.3123G>A p.L1041= | Silent (SNP) | VAF 8/135 reads (6%) | catalogued as COSV52168340; called by muse, mutect2
- TAOK2 | c.2127G>A p.Q709= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV99665728; called by muse, mutect2, varscan2
- TENM1 | c.1101G>T p.G367= | Silent (SNP) | VAF 15/141 reads (11%) | catalogued as COSV100951243; called by muse, mutect2, varscan2
- TLN1 | c.7479G>A p.K2493= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV100148366; called by muse, mutect2, varscan2
- TMEM255A | c.87C>A p.S29= | Silent (SNP) | VAF 22/128 reads (17%) | catalogued as COSV59029194; called by muse, mutect2, varscan2
- TRRAP | c.2496G>T p.V832= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as COSV100723188; called by muse, mutect2, varscan2
- TSPYL5 | c.576G>C p.G192= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as COSV100439180; called by muse, mutect2, varscan2
- XDH | c.756C>T p.H252= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as COSV101052511; called by muse, mutect2, varscan2
- ZNF770 | c.711C>T p.I237= | Silent (SNP) | VAF 4/82 reads (5%) | catalogued as COSV100696080; called by muse, mutect2
- AL353804.7 | chrX:73845488 T>C | 5'Flank (SNP) | VAF 20/105 reads (19%) | called by muse, mutect2, varscan2
- CCNQP1 | n.508G>T | RNA (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- SNX5 | c.51+5594A>G | Intron (SNP) | VAF 25/85 reads (29%) | catalogued as COSV100899119; called by muse, mutect2, varscan2
